Surgical pathology report (de-identified scan), TCGA case TCGA-06-0644, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0644-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

TCC-A-06-0644

=====

CLINICAL HISTORY

The patient is [REDACTED] with a left parietal tumor.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, left parietal, excision biopsy

B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. B. Brain, left parietal tumor, resection: gliosarcoma (WHO grade IV)
(see microscopic description and comment).

COMMENT

The results of MGMT promoter methylation analysis will be reported as an addendum.

=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing was done on blocks

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in

[page 2 of 3]
[REDACTED]

the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, left parietal tumor, excisional biopsy: malignant neoplasm, defer further characterization to permanent sections.

[REDACTED]

GROSS DESCRIPTION

A.

SPECIMEN: Left parietal tumor.

FIXATIVE: None.

GENERAL: A 2.0 x 1.3 x 0.7 cm. irregular pale tan tissue fragment submitted for frozen section evaluation. Sectioned.

SECTIONS: A1-FS frozen section remnant; A2,A3 remainder for permanent sections.

B.

SPECIMEN: Left parietal tumor.

FIXATIVE: None.

GENERAL: Received is a 1.5 x 1 x 0.8 cm gray-white rubbery tissue fragment.

SECTIONS: The specimen is sectioned and submitted entirely in cassette B1.

[REDACTED]

MICROSCOPIC DESCRIPTION

Sections of specimens A and B show a histologically complex neoplasm consisting of pleomorphic atypical cells. Many tumor cells are spindle-shaped and arranged in streaming fascicles. Other areas show whorl formation. Epithelioid tumor cells with moderately abundant cytoplasm are also present. Mitotic figures are frequent. Both focal and geographic necrosis is present. Immunostains performed on sections from block B1 reveal that many tumor cells are vimentin immunopositive. Many areas of the tumor are GFAP immunopositive, particularly islands of tumor cells which are less spindle-shaped. Focal pan-cytokeratin (CK) positivity, and patchy muscle-specific actin positivity of tumor spindle cells is noted. The tumor is negative for CK7, CK20, TTF1 and HMB45.

ICD-9(s):

191.9 191.9

[REDACTED]

Histo Data

Part A: Brain, left parietal, excision biopsy

Taken:	[REDACTED]	Received:	[REDACTED]
Stain/cnt		Block	Ordered
H/E x 1		1	[REDACTED]
			Comment

[REDACTED]

[page 3 of 3]
[REDACTED]

H/E x 1	2
H/E x 1	3
MGMT x 1	3

Part B: Brain, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
HHF35-DA x 1	1	[REDACTED]	
mGFAP-DA x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
HMB45-DA x 1	1	[REDACTED]	
KeratinSu x 1	1	[REDACTED]	
CK20-DA x 1	1	[REDACTED]	
CK7-DA x 1	1	[REDACTED]	
MGMT x 1	1	[REDACTED]	
S100-DA x 1	1	[REDACTED]	
TTF1-DA x 1	1	[REDACTED]	
Vim-DA x 1	1	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 9fedbbfd-80e1-45a4-974d-196cd84a2fed (TCGA-06-0644.91FA8B36-59D2-4820-9CE0-14C8B7B38934.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).